Surgical pathology report (de-identified scan), TCGA case TCGA-UY-A78M, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UY-A78M-01A (Primary Tumor).

[page 1 of 3]
ICD -O-3
Carcinoma, urothelial NOS
8/20/13

Site C67.9
Bladder NOS
C67.9

path
Overlapping lesion of bladder
C67.8
JW 8/20/13

FINAL PATHOLOGIC DIAGNOSIS

- A. Right ureter, biopsy (FS): No carcinoma identified.
- B. Left ureter, biopsy (FS): No carcinoma identified.
- C. Bladder, uterus with cervix, and bilateral ovaries and fallopian tubes; radical cystectomy, total abdominal hysterectomy, and bilateral salpingoophorectomy (exenteration):
- Bladder:
1. High-grade invasive urothelial (transitional cell) carcinoma, involving muscularis propria. See comment.
2. Focal carcinoma in situ.
3. No carcinoma seen in three pericystic lymph nodes (0/3).
- Uterus: Cervix, endometrium, myometrium, and serosa with no significant pathologic abnormality; no carcinoma identified.
- Bilateral ovaries: Atrophic ovaries with calcified blood vessels; no carcinoma identified.
- Bilateral fallopian tubes: No significant pathologic abnormality; no carcinoma identified.
- D. Right pelvic lymph node, dissection: Metastatic urothelial (transitional cell) carcinoma in two of eight lymph nodes (2/8).
- E. Left pelvic lymph node, dissection: No carcinoma identified in six lymph nodes (0/6).
- F. Final ureter, left, biopsy: No carcinoma identified.

[page 2 of 3]
G. Final ureter, right, biopsy: No carcinoma identified.

COMMENT:

Bladder Tumor Synoptic Comment

1. Tumor type: Urothelial (transitional cell) carcinoma.
2. Tumor grade: High-grade.
3. Tumor size: 4.0 cm.
4. Extent of tumor in bladder: Invasion into outer half of muscularis propria.
5. Lymphatic/vascular invasion: Not seen.
6. Epithelial abnormalities in bladder: Carcinoma in situ.
7. Extension of tumor into organs adjacent to bladder: Absent.
8. Surgical margins:
- Urethral margin: Free of tumor.
- Right ureter margin: Free of tumor.
- Left ureter margin: Free of tumor.
- Perivesical margin: Free of tumor.
9. Lymph nodes: 2 of 17 lymph nodes contain metastatic tumor; the largest metastatic deposit measures 1.3 cm in greatest dimension; there is no extranodal tumor growth.
10. Other pathologic findings in bladder: None.
11. AJCC/UICC stage: pT2bN2Mx.
12. Additional comments: None.
-

Specimen(s) Received

A: Right ureter (FS)
B: Left ureter (FS)
C: Bladder
D: Right pelvic lymph node
E: Left pelvic lymph node
F: Final ureter, left
G: Final ureter, right

Clinical History

The patient is an 85-year-old woman with bladder cancer. She undergoes anterior pelvic exenteration and bilateral pelvic lymph node dissection.

Gross Description

The specimen is received in seven parts, each labeled with the patient's name and medical record number. Parts E-G are received in formalin.

Part A is received fresh and is additionally labeled "1 - right ureter." It consists of a segment of ureter, measuring 0.3 cm in diameter. The specimen is entirely submitted for frozen section diagnosis as FS1, with the frozen section remnant submitted in cassette A1.

Part B is received fresh and is additionally labeled "#2 left ureter." It consists of a single segment of ureter, measuring 0.4 cm in diameter and 0.2 cm in thickness. The specimen is entirely submitted for frozen section diagnosis as FS2, with the frozen section remnant submitted in cassette B1.

Part C is received fresh and is additionally labeled "#3 bladder." It consists of a bladder and urethra, weighing 290 gm. Attached to the bladder is a uterus and bilateral adnexa. The specimen is inked in black and opened in the anterior fashion. The left adnexa is inked in green and the right adnexa in blue ink for orientation. The posterior aspect of the uterus is inked in red ink for orientation.

The bladder is remarkable for a tan-white, fungating mass that extends over the surface of the posterior wall onto the right and left lateral walls. The mass does not involve the anterior walls grossly. The mass covers the right ureteral opening. It extends to within a distance of 0.9 cm of the urethral opening. The mass lies 5.2 cm from the distal urethral margin. The mass measures 4.0 cm from right to left and 3.5 cm from superior to inferior, and it extends to a depth of 0.4 cm grossly. Representative sections of the bladder

[page 3 of 3]
and urethra are submitted as follows:

- Cassette C1: Distal urethral margin.
- Cassette C2: Left ureteral margin.
- Cassette C3: Inferior-posterior-central bladder.
- Cassette C4: Superior-posterior-central bladder.
- Cassette C5: Left superior-lateral wall.
- Cassette C6: Left inferior-lateral wall.
- Cassette C7: Right superior-lateral wall.
- Cassette C8: Right superior-lateral wall.
- Cassette C9: Right inferior-lateral wall, approaching serosal surface.
- Cassette C10: Anterior wall.

The uterus measures 5.8 cm from superior to inferior, 3.6 cm from cornu to cornu, and 2.3 cm from anterior to posterior. The cervical os is round and measures 0.5 cm in diameter. The right ovary and fallopian tube measure 3.9 x 2.8 x 1.2 cm. The left fallopian tube and ovary measure 3.8 x 2.8 x 0.8 cm. The endocervix and endometrium are grossly unremarkable. No mass defects are identified. The endocervix measures approximately 2.3 cm in length. The endometrium has an average thickness of <0.1 cm. The myometrium measures 1.1 cm in average thickness. The right ovary is bivalved to reveal a cavitory space, measuring 0.8 cm in average diameter, that has no fluid. The left ovary and fallopian tube are grossly unremarkable. Representative sections of the uterus and adnexa are submitted as follows:

- Cassette C11: Anterior cervix.
- Cassette C12: Posterior cervix.
- Cassette C13: Anterior myometrium and endometrium.
- Cassette C14: Posterior myometrium and endometrium.
- Cassette C15: Right ovary and right fallopian tube.
- Cassette C16: Left ovary and left fallopian tube.
- Cassette C17: Candidate pericystic lymph nodes.

Part D is received fresh and is additionally labeled "right pelvic lymph node fresh." It consists of multiple fragments of tan-yellow, fibrofatty tissue, measuring 5.2 x 4.1 x 2.0 cm in aggregate. A small portion of one lymph node is submitted for tissue banking. Candidate lymph nodes are submitted as follows:

- Cassette D1: One lymph node, bisected, one half inked in blue.
- Cassette D2: One lymph node, bisected, one half inked in blue.
- Cassette D3: Candidate lymph nodes.
- Cassette D4: Candidate lymph nodes, submitted between tissue paper.

Part E is additionally labeled "#5 left pelvic lymph nodes." It consists of fibrofatty sot tissue measuring 2.0 x 1.5 x 0.4 cm. The specimen is entirely submitted as follows:

- Cassette E1: One lymph node, bisected, one half inked in blue.
- Cassettes E2-E4: Candidate lymph nodes.

Part F, additionally labeled "final ureter left," consists of a 2.0 x 0.5 x 0.5 cm fragment of pink-tan tube with surrounding yellow-tan fat. The tube measures 0.5 cm in greatest diameter. The tip of the specimen is inked, and the specimen is serially sectioned and entirely submitted in cassette F1.

Part G, additionally labeled "final right ureter," consists of a single, irregularly shaped fragment of pink-tan tube with surrounding yellow-tan fat measuring 2.0 x 1.0 x 0.5 cm in greatest dimension. The central pink-tan tube measures 0.5 cm in diameter. The tip of the specimen is inked, and the specimen is serially sectioned and entirely submitted in cassette G1.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Criteria	lw 8/9/13	Yes	No

Source: NCI Genomic Data Commons file 3583307c-51ca-4190-b380-8cb4c2cff3ca (TCGA-UY-A78M.04F6BAED-CAA0-4396-9332-3EB8BA902895.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).